Somatic mutation profile of tumor specimen TCGA-73-4659-01A (aliquot TCGA-73-4659-01A-01D-1265-08) from TCGA case TCGA-73-4659, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 66.4 years (24,253 days).
Specimen TCGA-73-4659-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67285c0c-aa78-4b02-bd0d-824fcce3bee0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-73-4659-11A (Solid Tissue Normal), aliquot TCGA-73-4659-11A-01D-1265-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/817fc690-3aed-489d-a74d-d74f53610656

The open-access MAF lists 232 somatic variants for this specimen: 179 protein-altering or splice-affecting, 50 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 50, Nonsense Mutation 9, Frame Shift Del 7, Splice Site 5, Splice Region 4, Frame Shift Ins 3, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.157dup p.D53Gfs*110 | Frame Shift Ins (INS) | VAF 24/45 reads (53%) | catalogued as rs1131690917; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCG4 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.492); catalogued as COSV56644615; called by muse, mutect2, varscan2
- ADAM19 | c.1066G>T p.D356Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57434231; called by muse, mutect2, varscan2
- ADAMTS12 | c.3235C>G p.R1079G | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV100711235, COSV61269403; called by muse, mutect2, varscan2
- ADAMTS16 | c.2309G>T p.G770V | Missense Mutation (SNP) | VAF 75/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56982813, COSV56997422; called by muse, mutect2, varscan2
- ADCY8 | c.1641G>A p.G547= | Splice Region (SNP) | VAF 70/276 reads (25%) | catalogued as COSV53916065; called by muse, mutect2, varscan2
- ADGRB3 | c.577T>A p.Y193N | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV65406166, COSV65409341; called by muse, mutect2, varscan2
- ADGRF4 | c.113G>T p.S38I | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51954558; called by muse, mutect2, varscan2
- ANGPT1 | c.1393G>C p.G465R | Missense Mutation (SNP) | VAF 46/339 reads (14%) | SIFT tolerated (0.95); PolyPhen benign (0.346); catalogued as COSV52447409, COSV52458150; called by muse, mutect2, varscan2
- ANKFN1 | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV59452900; called by muse, mutect2, varscan2
- ANO3 | c.2579G>T p.C860F | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56799008; called by muse, varscan2
- APBB2 | c.956G>T p.R319L (on ENST00000295974 / NM_001166050.2; = p.R320L on NM_004307.2) | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV55947103, COSV55956888; called by muse, mutect2, varscan2
- APC | c.4240G>A p.V1414I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs755300914, COSV57321918, COSV57322665, COSV57326384; called by muse, mutect2, varscan2
- ASTN1 | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 29/319 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV56066712, COSV56075935; called by muse, mutect2, varscan2
- ASXL3 | c.2207T>C p.L736P | Missense Mutation (SNP) | VAF 119/461 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52472162; called by muse, mutect2, varscan2
- ATF7IP | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.536); catalogued as COSV53773795; called by muse, mutect2, varscan2
- ATM | c.4309A>T p.R1437* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53757213; called by muse, mutect2, varscan2
- BCAN | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61257971; called by muse, mutect2, varscan2
- BCAS1 | c.1607T>A p.L536Q | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65087813; called by muse, mutect2, varscan2
- BLID | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 36/178 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.117); catalogued as COSV73340298; called by muse, mutect2, varscan2
- BMP7 | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67780641; called by muse, mutect2, varscan2
- CACNA1S | c.2668A>T p.I890F | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as COSV62941571; called by muse, mutect2, varscan2
- CCKBR | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100582976, COSV58103264; called by muse, mutect2, varscan2
- CD63 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as rs200393279; called by muse, mutect2
- CDK5RAP2 | c.4280G>T p.G1427V | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.277); catalogued as COSV62576124; called by muse, mutect2, varscan2
- CENPF | c.7144G>A p.G2382S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs779258589, COSV65276580; called by muse, mutect2
- CFAP91 | c.695C>T p.P232L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1294639557, COSV56342585; called by muse, mutect2, varscan2
- CGN | c.3257C>T p.S1086F | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54971764; called by muse, mutect2, varscan2
- CHD8 | c.2229C>T p.P743= (on ENST00000646647 / NM_001170629.2; = p.P464= on NM_020920.4) | Splice Region (SNP) | VAF 11/41 reads (27%) | catalogued as rs766074272, COSV67871621; ClinVar: likely benign; called by muse, mutect2
- CHD8 | c.1399G>A p.E467K (on ENST00000646647 / NM_001170629.2; = p.E188K on NM_020920.4) | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67871624; called by muse, mutect2, varscan2
- CLUL1 | c.642A>T p.Q214H | Missense Mutation (SNP) | VAF 78/310 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV58112710; called by muse, mutect2, varscan2
- CNIH3 | c.464A>T p.Y155F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs759640484, COSV55277796; called by muse, mutect2, varscan2
- COL11A1 | c.2861C>A p.T954N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV62204454; called by muse, mutect2, varscan2
- COPG1 | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as rs746648581, COSV59115350; called by muse, mutect2, varscan2
- DEFA6 | c.124C>A p.R42S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.613); catalogued as COSV52406120, COSV52406301; called by muse, mutect2, varscan2
- DIP2A | c.148A>C p.I50L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59481896; called by muse, mutect2, varscan2
- DMRT1 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV66522726, COSV66522731; called by muse, mutect2, varscan2
- DNAH9 | c.3399A>T p.L1133F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV52360380; called by muse, varscan2
- DNAJB4 | c.619G>C p.G207R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100883478; called by muse, mutect2, varscan2
- DPP4 | c.286-1G>A p.X96_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100858979, COSV62108098; called by muse, mutect2, varscan2
- DSN1 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV65519629; called by muse, mutect2, varscan2
- DST | c.15737C>T p.P5246L (on ENST00000361203 / NM_001374722.1; = p.P2834L on NM_015548.5) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.746); catalogued as rs189808261, COSV55026102; called by muse, mutect2, varscan2
- DYNC1I1 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV61459821; called by muse, varscan2
- E2F7 | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV59741695; called by muse, mutect2, varscan2
- EIF4B | c.1028A>G p.K343R | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); catalogued as COSV50405122; called by muse, mutect2, varscan2
- ELAVL2 | c.489C>T p.G163= | Splice Region (SNP) | VAF 34/173 reads (20%) | catalogued as rs773876308, COSV56365624; called by muse, mutect2, varscan2
- ELMOD1 | c.135G>T p.K45N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.052); catalogued as COSV56194158; called by muse, mutect2, varscan2
- EPB41L2 | c.2514G>T p.M838I | Missense Mutation (SNP) | VAF 57/233 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100441245; called by muse, mutect2, varscan2
- EPB41L2 | c.2513T>A p.M838K | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as COSV100441247; called by muse, mutect2, varscan2
- EPG5 | c.5564T>A p.L1855Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56352524; called by muse, mutect2, varscan2
- EPHA6 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67581737; called by muse, mutect2, varscan2
- ESRRB | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55060443, COSV55063898; called by muse, mutect2, varscan2
- F11 | c.1641G>C p.K547N | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV53002525; called by muse, mutect2, varscan2
- F5 | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as COSV63125942; called by muse, mutect2
- FAHD2A | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.061); catalogued as rs771445507, COSV99272202; called by muse, mutect2, varscan2
- FAM167A | c.232G>T p.G78W | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV52705449, COSV99461731; called by muse, mutect2, varscan2
- FBXL18 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.591); catalogued as COSV66107753; called by muse, mutect2, varscan2
- FBXL4 | c.1688A>C p.Q563P | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV57748119; called by muse, mutect2, varscan2
- FLNC | c.7407C>G p.I2469M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.292); catalogued as rs1563005140, COSV57959687; called by muse, mutect2, varscan2
- GCC2 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.035); catalogued as COSV59178162; called by muse, varscan2
- GCM1 | c.321G>C p.K107N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52523091; called by muse, varscan2
- GJC1 | c.798G>T p.R266S | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV57912174; called by muse, mutect2
- GPN2 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV64652339; called by muse, mutect2, varscan2
- GTF3C1 | c.5461G>C p.D1821H | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.145); catalogued as COSV62242765; called by muse, mutect2, varscan2
- HABP2 | c.1470T>A p.S490R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV63492293; called by muse, mutect2, varscan2
- HBD | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as COSV53082987; called by muse, mutect2, varscan2
- HERC2 | c.7019G>C p.R2340P | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55335336, COSV55344257; called by muse, mutect2, varscan2
- IGHV5-51 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs199503234; called by muse, mutect2, varscan2
- IGLV3-1 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as rs145382269; called by muse, mutect2, varscan2
- ITLN1 | c.158-1G>T p.X53_splice | Splice Site (SNP) | VAF 13/94 reads (14%) | catalogued as COSV58274453, COSV58274948; called by muse, mutect2, varscan2
- KCNQ2 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100610648, COSV60436325; called by muse, mutect2, varscan2
- KIF4B | c.1024G>C p.V342L | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs781104821, COSV70530341; called by muse, mutect2, varscan2
- KIFBP | c.1809G>T p.M603I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62832058; called by muse, mutect2, varscan2
- KRT73 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 32/117 reads (27%) | catalogued as rs759670534, COSV59840268; called by muse, mutect2, varscan2
- LUZP1 | c.2809C>G p.P937A | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.034); catalogued as COSV56502120, COSV56503124; called by muse, mutect2
- MED12L | c.3285G>T p.Q1095H | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (0.78); PolyPhen probably damaging (0.979); catalogued as COSV56386669; called by muse, mutect2, varscan2
- MED13L | c.4870G>T p.D1624Y | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as COSV56124492; called by muse, mutect2, varscan2
- MINK1 | c.323G>T p.C108F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61791362; called by muse, mutect2, varscan2
- MRGPRX4 | c.203T>C p.L68P | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756601981, COSV100049818; called by muse, mutect2, varscan2
- MRPL37 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV55277937; called by muse, mutect2, varscan2
- MS4A12 | c.732C>A p.S244R | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV50014974; called by muse, mutect2, varscan2
- MYH13 | c.391T>A p.W131R | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV52835070; called by muse, mutect2, varscan2
- MYH6 | c.4860G>T p.M1620I | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV62452475, COSV62452501; called by muse, mutect2, varscan2
- MYPN | c.1986G>C p.Q662H | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62735718; called by muse, mutect2, varscan2
- NAT16 | c.434A>T p.Q145L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100296359; called by muse, mutect2, varscan2
- NAV3 | c.2183G>T p.R728M | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57094968; called by muse, mutect2, varscan2
- NCAPH2 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.61); catalogued as rs758319676, COSV52688604; called by muse, mutect2, varscan2
- NCKAP5 | c.2386C>G p.Q796E | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as COSV58458770; called by muse, mutect2
- NLRP11 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374796362, COSV100789747; called by muse, mutect2, varscan2
- NLRP7 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs759837769, COSV60173232; called by muse, mutect2, varscan2
- NOD2 | c.2438G>C p.C813S | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56052873; called by muse, mutect2, varscan2
- NOX5 | c.980T>A p.V327E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV52992309; called by muse, mutect2, varscan2
- NRAP | c.2680G>T p.G894C (on ENST00000359988 / NM_001322945.2; = p.G859C on NM_006175.4) | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV63492299; called by muse, mutect2, varscan2
- NRXN1 | c.4220T>C p.I1407T | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV60505523; called by muse, mutect2, varscan2
- NTRK1 | c.429-1G>T p.X143_splice | Splice Site (SNP) | VAF 57/145 reads (39%) | catalogued as CS991471, COSV100693682; called by muse, mutect2, varscan2
- NTRK1 | c.429G>T p.L143= | Splice Region (SNP) | VAF 56/145 reads (39%) | catalogued as COSV100693685; called by muse, mutect2, varscan2
- NUP133 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV54573219; called by muse, mutect2, varscan2
- NUP153 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746446124, COSV50451805; called by muse, mutect2, varscan2
- NXPH1 | c.62G>T p.C21F | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV68314549, COSV68317077; called by muse, mutect2, varscan2
- OFD1 | c.86A>G p.D29G | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100407071; called by muse, mutect2, varscan2
- OR14I1 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV61200277; called by muse, mutect2, varscan2
- OR2M3 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 206/620 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV71758868, COSV71759174; called by muse, mutect2, varscan2
- OR2T12 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58778440; called by muse, mutect2, varscan2
- OR2T33 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV100532328, COSV58816478; called by muse, mutect2
- OR4A15 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 103/429 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs746232440, COSV59033682, COSV59035771; called by muse, mutect2, varscan2
- OR5W2 | c.656G>A p.C219Y | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV60617186; called by muse, mutect2, varscan2
- OR5W2 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV60617195; called by muse, mutect2, varscan2
- PCDH15 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs763829592, COSV57348690; called by muse, mutect2, varscan2
- PCDHA5 | c.1680C>A p.N560K | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV100972487, COSV65349512; called by muse, mutect2, varscan2
- PCDHB1 | c.2400T>A p.D800E | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs781904410, COSV60631985; called by muse, mutect2, varscan2
- PCDHGA7 | c.617G>T p.R206L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.078); catalogued as COSV53898785, COSV53984598; called by muse, mutect2, varscan2
- PDE6A | c.1929C>A p.S643R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as rs1173817463, COSV54929292; called by muse, mutect2, varscan2
- PGBD1 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.378); catalogued as COSV52554619; called by muse, mutect2, varscan2
- POU1F1 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV55463051; called by muse, mutect2, varscan2
- PPP1R26 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63356330; called by muse, mutect2, varscan2
- PRKD1 | c.599G>T p.R200M | Missense Mutation (SNP) | VAF 79/396 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59576735, COSV59579797; called by muse, mutect2, varscan2
- PRUNE2 | c.8437G>T p.D2813Y | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56317869; called by muse, mutect2, varscan2
- PTH2R | c.881G>T p.W294L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99782760; called by muse, mutect2, varscan2
- PTPRD | c.2411C>A p.T804K | Missense Mutation (SNP) | VAF 18/212 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV61962255; called by muse, mutect2
- PTPRT | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as rs1424048902, COSV61965308, COSV61997986; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2333G>T p.G778V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.733); catalogued as COSV54761934; called by muse, mutect2, varscan2
- RAB40B | c.163A>T p.T55S | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV99483783; called by muse, mutect2, varscan2
- RASGEF1B | c.559G>C p.V187L | Missense Mutation (SNP) | VAF 26/197 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52338199; called by muse, mutect2, varscan2
- RFPL2 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1569346381, COSV50713405; called by muse, mutect2, varscan2
- RHCG | c.1113-2A>T p.X371_splice | Splice Site (SNP) | VAF 7/117 reads (6%) | catalogued as COSV51517076; called by muse, mutect2
- RHEB | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs867628277, COSV51262704, COSV51263083; called by muse, mutect2
- RIMS2 | c.1018G>T p.A340S (on ENST00000666250 / NM_001348490.2; = p.A148S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51699653; called by muse, mutect2, varscan2
- RNF121 | c.306G>T p.W102C | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV62317200; called by muse, mutect2, varscan2
- RSRP1 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs775920913, COSV99682704; called by muse, varscan2
- RTTN | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55348191; called by muse, mutect2, varscan2
- SBNO1 | c.4021G>T p.D1341Y (on ENST00000420886; = p.D1340Y on NM_018183.5) | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57343548; called by muse, mutect2, varscan2
- SH3TC2 | c.3667C>A p.Q1223K | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV60465438; called by muse, mutect2, varscan2
- SIX4 | c.166G>C p.G56R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.11); catalogued as rs1489227511, COSV99382445; called by muse, varscan2
- SLC5A12 | c.568G>T p.V190F | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.616); catalogued as COSV54822942; called by muse, mutect2
- SLC6A2 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54916084; called by muse, mutect2, varscan2
- SMOC2 | c.851C>A p.T284K (on ENST00000356284 / NM_001166412.2; = p.T295K on NM_022138.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV62440719; called by muse, mutect2, varscan2
- SORCS3 | c.1400G>T p.R467L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs147155519; called by muse, mutect2, varscan2
- SPHKAP | c.3268G>T p.D1090Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60886206; called by muse, mutect2, varscan2
- SPOPL | c.1026G>T p.W342C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV54514677; called by muse, mutect2, varscan2
- ST18 | c.2977C>T p.L993F | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761756701, COSV52500601; called by muse, mutect2, varscan2
- SYNE3 | c.1766C>G p.S589* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV62080690; called by muse, mutect2, varscan2
- TBCD | c.1408G>T p.V470L | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs372560471; called by muse, mutect2, varscan2
- TEX33 | c.666G>T p.K222N (on ENST00000381821 / NM_001163857.2; = p.K137N on NM_178552.4) | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67822438; called by muse, mutect2, varscan2
- TEX47 | c.696G>T p.M232I | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV51879503; called by muse, mutect2, varscan2
- THSD7B | c.2584C>A p.Q862K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV55710631; called by muse, mutect2, varscan2
- TLR4 | c.2423G>T p.W808L (on ENST00000355622 / NM_138554.5; = p.W768L on NM_003266.4) | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.914); catalogued as COSV100842665; called by muse, mutect2, varscan2
- TLR4 | c.2424G>T p.W808C (on ENST00000355622 / NM_138554.5; = p.W768C on NM_003266.4) | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100842833, COSV62922301; called by muse, mutect2
- TRIO | c.1854G>T p.Q618H | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100710799; called by muse, mutect2, varscan2
- TRIO | c.1854+1G>T p.X618_splice | Splice Site (SNP) | VAF 42/224 reads (19%) | catalogued as COSV100710800; called by muse, mutect2, varscan2
- TTBK1 | c.2641G>T p.V881L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.413); catalogued as COSV52493895; called by muse, mutect2
- TUBA3D | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 24/311 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.488); catalogued as COSV58312522; called by muse, mutect2
- TUBGCP2 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV53306859; called by muse, mutect2, varscan2
- TXLNB | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 52/186 reads (28%) | catalogued as COSV64443880, COSV64444790; called by muse, mutect2, varscan2
- UBAP2L | c.3164G>T p.G1055V | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1310990004, COSV55176708, COSV55183191; called by muse, mutect2, varscan2
- UNC5A | c.306G>T p.M102I | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV56170312; called by muse, mutect2, varscan2
- USF2 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs757173577, COSV99723480; called by muse, mutect2, varscan2
- USP22 | c.431A>G p.K144R | Missense Mutation (SNP) | VAF 41/148 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV54947616; called by muse, mutect2, varscan2
- VPS13B | c.9555G>T p.M3185I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV62149093; called by muse, mutect2
- XIRP2 | c.2017C>A p.Q673K (on ENST00000628543; = p.Q848K on NM_152381.6) | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.652); catalogued as COSV54715874, COSV54726456; called by muse, mutect2, varscan2
- XPOT | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 29/119 reads (24%) | catalogued as COSV60346513, COSV60346680; called by muse, mutect2, varscan2
- ZFP42 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58818275; called by muse, mutect2, varscan2
- ZNF23 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs368192477, COSV61841298; called by muse, mutect2, varscan2
- ZNF280D | c.2654G>C p.R885P | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs184815636, COSV50998538; called by muse, mutect2, varscan2
- AMER2 | c.1657del p.D553Tfs*32 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | called by mutect2, pindel, varscan2
- CABS1 | c.116del p.T39Kfs*13 | Frame Shift Del (DEL) | VAF 23/121 reads (19%) | called by mutect2, pindel, varscan2
- CHL1 | c.844_845insA p.P282Hfs*62 (on ENST00000397491 / NM_001253387.1; = p.P298Hfs*62 on NM_006614.4) | Frame Shift Ins (INS) | VAF 34/88 reads (39%) | called by mutect2, varscan2
- CYP4B1 | c.1432_1433del p.L478Gfs*73 | Frame Shift Del (DEL) | VAF 17/164 reads (10%) | called by pindel, varscan2
- HES1 | c.729del p.V244Sfs*72 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- IGLV7-43 | c.230C>A p.S77Y | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- IQGAP2 | c.4249G>T p.E1417* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | called by mutect2, varscan2
- IQGAP2 | c.4253dup p.L1418Ffs*12 | Frame Shift Ins (INS) | VAF 9/54 reads (17%) | called by mutect2, pindel, varscan2
- KLHL18 | c.646del p.R216Gfs*42 | Frame Shift Del (DEL) | VAF 22/94 reads (23%) | called by mutect2, pindel, varscan2
- PLEKHH3 | c.319C>G p.R107G | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); called by muse, mutect2
- SIRPB1 | c.148del p.A50Pfs*7 | Frame Shift Del (DEL) | VAF 26/135 reads (19%) | called by mutect2, pindel, varscan2
- SLC8A2 | c.1232C>A p.S411Y | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.355); called by muse, mutect2
- SPATA31A1 | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by mutect2, varscan2
- TUBA3E | c.583C>A p.L195M | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASHC2A | c.2251G>T p.E751* | Nonsense Mutation (SNP) | VAF 57/337 reads (17%) | called by muse, mutect2, varscan2
- ZFYVE26 | c.3723del p.Q1242Kfs*9 | Frame Shift Del (DEL) | VAF 36/176 reads (20%) | called by mutect2, pindel, varscan2
- ACTN1 | c.2094G>T p.A698= | Silent (SNP) | VAF 59/157 reads (38%) | catalogued as COSV51994683, COSV99518533; called by muse, mutect2, varscan2
- ADAMTS12 | c.4068T>A p.P1356= | Silent (SNP) | VAF 41/178 reads (23%) | catalogued as COSV61269392; called by muse, mutect2, varscan2
- ADH1B | c.195T>A p.I65= | Silent (SNP) | VAF 38/200 reads (19%) | catalogued as COSV59297488; called by muse, mutect2, varscan2
- ANO6 | c.2715A>G p.L905= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV57664033; called by mutect2, varscan2
- ARMH3 | c.1104G>T p.L368= | Silent (SNP) | VAF 40/215 reads (19%) | catalogued as COSV64236450; called by muse, mutect2, varscan2
- CCDC61 | c.1419C>T p.S473= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs758587949, COSV50517119; called by muse, mutect2
- CCN4 | c.513G>T p.R171= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs929291998, COSV51533704; called by muse, mutect2, varscan2
- CNTN4 | c.2022A>T p.T674= | Silent (SNP) | VAF 138/395 reads (35%) | catalogued as COSV61876197; called by muse, mutect2, varscan2
- COLEC11 | c.231C>A p.G77= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV52595274; called by muse, mutect2, varscan2
- CYTIP | c.687G>T p.G229= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV51634630; called by muse, mutect2, varscan2
- DCAF12L1 | c.795G>A p.V265= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs1191677607, COSV64422215; called by muse, mutect2, varscan2
- EID2B | c.42C>T p.P14= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs778891784, COSV100411044, COSV58319219; called by muse, mutect2
- ELF4 | c.414C>T p.A138= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as rs1356533852, COSV57453664; called by muse, mutect2, varscan2
- F13B | c.1695C>T p.A565= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs1361784557, COSV100803342, COSV66374740; called by muse, mutect2, varscan2
- FREM1 | c.6090G>T p.L2030= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV66526508; called by muse, mutect2, varscan2
- GJD2 | c.534A>C p.P178= | Silent (SNP) | VAF 33/227 reads (15%) | catalogued as COSV51749233; called by muse, mutect2, varscan2
- GLI1 | c.2070C>T p.P690= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV57364541; called by muse, mutect2, varscan2
- HNRNPR | c.108A>T p.A36= | Silent (SNP) | VAF 72/234 reads (31%) | catalogued as COSV56421143, COSV56422893; called by muse, mutect2, varscan2
- KIN | c.1098A>T p.S366= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV65430997; called by muse, mutect2
- KRT84 | c.402C>A p.A134= | Silent (SNP) | VAF 86/299 reads (29%) | catalogued as COSV57772472, COSV99230985; called by muse, mutect2, varscan2
- LGI1 | c.63T>C p.Y21= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs1300409685, COSV65058655; called by muse, mutect2, varscan2
- LHX1 | c.402C>G p.T134= | Silent (SNP) | VAF 9/49 reads (18%) | called by muse, mutect2, varscan2
- LNX2 | c.520T>C p.L174= | Silent (SNP) | VAF 90/271 reads (33%) | catalogued as rs1257227297, COSV60336967; called by muse, mutect2, varscan2
- LRRK1 | c.369A>T p.P123= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV52618856; called by muse, mutect2, varscan2
- MMP17 | c.546C>A p.A182= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV62180331; called by muse, mutect2, varscan2
- NLRP4 | c.1023G>T p.P341= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs746364962, COSV56717636, COSV56718167; called by muse, mutect2, varscan2
- NPC1L1 | c.2460G>T p.P820= | Silent (SNP) | VAF 47/175 reads (27%) | catalogued as COSV56927348; called by muse, mutect2, varscan2
- NUP155 | c.84G>T p.R28= | Silent (SNP) | VAF 33/162 reads (20%) | catalogued as COSV51532039; called by muse, mutect2, varscan2
- OR11H6 | c.612A>T p.A204= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1412702535, COSV59644597; called by muse, mutect2, varscan2
- OR2T4 | c.312G>A p.A104= | Silent (SNP) | VAF 151/521 reads (29%) | catalogued as rs766681087, COSV63543420; called by muse, mutect2, varscan2
- OR5AU1 | c.78G>A p.L26= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV100436188; called by muse, mutect2, varscan2
- OR6F1 | c.39C>A p.L13= | Silent (SNP) | VAF 36/213 reads (17%) | catalogued as COSV57468535; called by muse, mutect2, varscan2
- PCDHA13 | c.1293C>A p.G431= | Silent (SNP) | VAF 43/169 reads (25%) | catalogued as COSV56523956; called by muse, mutect2, varscan2
- PIAS3 | c.864A>G p.K288= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV65171726; called by muse, mutect2, varscan2
- PLD4 | c.456G>A p.S152= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs573590569, COSV66915483; called by muse, mutect2, varscan2
- POTEE | c.2883C>A p.L961= | Silent (SNP) | VAF 8/44 reads (18%) | called by mutect2, varscan2
- PPP2R2D | c.777G>A p.L259= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs1564823070, COSV101409063, COSV70779446; called by muse, mutect2, varscan2
- PRDM10 | c.414G>A p.E138= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV58802888; called by muse, mutect2, varscan2
- PRKDC | c.7023G>C p.L2341= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV58057771; called by muse, mutect2
- REG3A | c.417C>G p.T139= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as COSV59408163, COSV59410497; called by muse, mutect2, varscan2
- RNF8 | c.405T>C p.C135= | Silent (SNP) | VAF 14/113 reads (12%) | catalogued as COSV100009824; called by muse, mutect2, varscan2
- SMC6 | c.1680A>T p.P560= | Silent (SNP) | VAF 48/162 reads (30%) | catalogued as COSV61176280; called by muse, mutect2, varscan2
- STAB2 | c.5505G>A p.L1835= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV66342475; called by muse, mutect2, varscan2
- TEP1 | c.2457A>T p.V819= | Silent (SNP) | VAF 36/123 reads (29%) | catalogued as COSV52995904; called by muse, mutect2, varscan2
- TIMD4 | c.648G>A p.E216= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV50857140; called by muse, mutect2, varscan2
- TLR4 | c.2010T>A p.G670= (on ENST00000355622 / NM_138554.5; = p.G630= on NM_003266.4) | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV62923742, COSV62924613; called by muse, mutect2, varscan2
- TMEM74B | c.210G>A p.E70= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as rs1568494152, COSV101121988; called by muse, mutect2, varscan2
- TNR | c.3603C>T p.F1201= | Silent (SNP) | VAF 49/224 reads (22%) | catalogued as rs765280460, COSV54898926; called by muse, mutect2, varscan2
- WWC2 | c.3021A>T p.P1007= | Silent (SNP) | VAF 15/113 reads (13%) | catalogued as COSV67860037; called by muse, mutect2, varscan2
- YY2 | c.762C>G p.V254= | Silent (SNP) | VAF 73/147 reads (50%) | catalogued as COSV63412056; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503707 G>C | 5'Flank (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- LINC00518 | n.906C>T | RNA (SNP) | VAF 35/112 reads (31%) | called by muse, mutect2, varscan2
- SNORD115-10 | n.54C>T | RNA (SNP) | VAF 39/382 reads (10%) | called by muse, varscan2
